Somatic mutation profile of tumor specimen TCGA-SI-A71O-01A (aliquot TCGA-SI-A71O-01A-12D-A33E-09) from TCGA case TCGA-SI-A71O, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 29.3 years (10,710 days).
Specimen TCGA-SI-A71O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5d13ee4-86f5-46dd-a633-dad89c5a44c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SI-A71O-10A (Blood Derived Normal), aliquot TCGA-SI-A71O-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eab462c2-3aa9-477c-9e85-a12963d4c2a0

The open-access MAF lists 31 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Intron 2, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Del 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APBB2 | c.2248C>T p.Q750* (on ENST00000295974 / NM_001166050.2; = p.Q751* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as COSV99922490; called by muse, mutect2, varscan2
- ARHGAP6 | c.1684C>G p.L562V | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV100272320; called by muse, mutect2, varscan2
- DAB1 | c.1640A>G p.E547G (on ENST00000371231; = p.E514G on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100976290; called by muse, mutect2, varscan2
- DACT1 | c.1949G>A p.G650D | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.51); catalogued as rs1184871353, COSV100241802; called by muse, mutect2, varscan2
- EHD1 | c.605A>G p.E202G | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100276859; called by muse, mutect2, varscan2
- FOXN3 | c.1439G>A p.G480E (on ENST00000261302; = p.G458E on NM_005197.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV54318178; called by mutect2, varscan2
- GPR83 | c.1053C>G p.N351K | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV99703663; called by muse, mutect2, varscan2
- INPP4A | c.2431G>A p.E811K (on ENST00000074304 / NM_001134224.1; = p.E772K on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50785493, COSV99302666; called by muse, mutect2, varscan2
- KCNH6 | c.2148+1G>A p.X716_splice | Splice Site (SNP) | VAF 10/33 reads (30%) | catalogued as rs764955692, COSV100120971; called by muse, mutect2, varscan2
- KCNN1 | c.304A>T p.K102* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99715870; called by muse, mutect2
- OR10G9 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.85); PolyPhen benign (0.021); catalogued as COSV100901480; called by muse, mutect2, varscan2
- SACS | c.6645C>G p.F2215L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV101207191; called by muse, mutect2, varscan2
- SACS | c.5937C>G p.F1979L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV101207393; called by muse, varscan2
- SEMA5B | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as COSV99531527; called by muse, mutect2, varscan2
- SPHKAP | c.4890G>C p.W1630C (on ENST00000392056 / NM_001142644.2; = p.W1601C on NM_030623.3) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100764069; called by muse, mutect2, varscan2
- SPHKAP | c.4732G>A p.E1578K (on ENST00000392056 / NM_001142644.2; = p.E1549K on NM_030623.3) | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60889879; called by muse, mutect2, varscan2
- TBX4 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99540139; called by muse, mutect2
- ZNF181 | c.1535C>A p.T512N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV101106256, COSV67627379; called by mutect2, varscan2
- ZNF81 | c.1643A>C p.H548P | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100095396; called by muse, mutect2, varscan2
- EYA1 | c.1697dup p.H567Afs*65 | Frame Shift Ins (INS) | VAF 20/74 reads (27%) | called by mutect2, pindel, varscan2
- GOLGA3 | c.68_69del p.L23Pfs*15 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by pindel, varscan2
- OR10G7 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.033); called by mutect2, varscan2
- POLR3B | c.265_267del p.E89del | In Frame Del (DEL) | VAF 41/76 reads (54%) | called by pindel, varscan2
- PRKDC | c.4092dup p.N1365* | Frame Shift Ins (INS) | VAF 11/30 reads (37%) | called by mutect2, varscan2
- DIRAS2 | c.234A>G p.K78= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV101005839; called by muse, mutect2, varscan2
- LORICRIN | c.840C>T p.G280= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100907272, COSV64201271; called by muse, mutect2, varscan2
- PCDHA1 | c.2025G>A p.A675= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs143057294; called by muse, mutect2, varscan2
- SCN1B | c.387C>T p.F129= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs891588693, COSV52894229; called by muse, varscan2
- SPRED3 | c.648C>A p.G216= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV100634198; called by muse, mutect2
- ANKRD33 | c.664+38G>A | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs371567187, COSV100001051; called by muse, mutect2
- TTN | c.10360+2499A>T | Intron (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100608892; called by muse, mutect2, varscan2
